MMRF case MMRF_2598 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f623b447-0185-4460-b4b6-c120845d3be5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.2 years (30,017 days); ISS stage: III; Days to last known disease status: 638 days (1.7 years); Days to last follow up: 638 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 10 days; Days to treatment end: 42 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 100 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 8.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Beta 2 Microglobulin 8.41 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.63 mmol/L; Albumin 30 g/L; Glucose 7.48 mmol/L.
- Day 100 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 4.57 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 7.3 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 31 g/L; Total Protein 7.2 g/dL; Glucose 11.8 mmol/L.
- Day 191 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.19 mg/dL; Immunoglobulin G 9.8 g/L; Immunoglobulin A 2.16 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 0.7 µg/mL; Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 10.3 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 361 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.33 mmol/L; Albumin 26 g/L; Total Protein 6.9 g/dL; Glucose 8.86 mmol/L.
- Day 276 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 7.39 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 0.6 µg/mL; Hemoglobin 6.94 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 5.45 mmol/L.
- Day 366 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Beta 2 Microglobulin 0.4 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.28 mmol/L; Albumin 31 g/L; Total Protein 6.6 g/dL; Glucose 7.87 mmol/L.
- Day 459 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 5.93 g/L; Immunoglobulin A 1.74 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 0.4 µg/mL; Lactate Dehydrogenase 4.32 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 14.2 ×10⁹/L; Absolute Neutrophil 11.5 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 26 g/L; Total Protein 6.1 g/dL; Glucose 9.46 mmol/L.
- Day 550 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Immunoglobulin A 1.99 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 5.13 µg/mL; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.23 mmol/L; Albumin 28 g/L; Total Protein 6.5 g/dL; Glucose 9.24 mmol/L.
- Day 638 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.88 mg/dL; Immunoglobulin G 6.33 g/L; Immunoglobulin A 1.74 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 0.4 µg/mL; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 14.6 ×10⁹/L; Absolute Neutrophil 11.2 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.35 mmol/L; Albumin 33 g/L; Total Protein 6.5 g/dL; Glucose 7.54 mmol/L.

Other clinical attributes
- Day 1: Weight: 63 kg; Height: 160 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2598_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2598_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
